Somatic mutation profile of tumor specimen MMRF_1895_1_BM_CD138pos (aliquot MMRF_1895_1_BM_CD138pos_T1_KBS5U_L06427) from MMRF case MMRF_1895, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 50.8 years (18,560 days).
Specimen MMRF_1895_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 71abc203-6571-4665-b391-e6ef9d811930.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_1895_1_PB_Whole (Blood Derived Normal), aliquot MMRF_1895_1_PB_Whole_C3_KBS5U_L06472; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0193b4a0-5d51-4376-9d22-894b89afdb99

The open-access MAF lists 81 somatic variants for this specimen: 35 protein-altering or splice-affecting, 9 silent, 37 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 30, 3'UTR 17, Intron 12, Silent 9, 5'UTR 4, Nonsense Mutation 3, RNA 2, 5'Flank 1, Frame Shift Del 1, Splice Site 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PTPN11 | c.181G>T p.D61Y | Missense Mutation (SNP) | VAF 39/84 reads (46%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs397507510, CD055729, CM021127, CM101143, COSV61004841, COSV61006072, COSV61006164; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ACTB | c.559_562del p.D187Tfs*3 | Frame Shift Del (DEL) | VAF 22/66 reads (33%) | catalogued as rs886041265; called by pindel, varscan2
- ANO1 | c.2609C>T p.P870L | Missense Mutation (SNP) | VAF 17/77 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs1319867351, COSV62444925; called by muse, mutect2, varscan2
- CAPN1 | c.2059C>T p.R687* | Nonsense Mutation (SNP) | VAF 138/194 reads (71%) | catalogued as rs1358242432; called by muse, mutect2, varscan2
- CAVIN2 | c.680G>C p.R227T | Missense Mutation (SNP) | VAF 14/178 reads (8%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.521); catalogued as COSV100414315; called by muse, mutect2
- CCSER1 | c.2547A>C p.Q849H | Missense Mutation (SNP) | VAF 75/131 reads (57%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.003); catalogued as COSV100397698; called by muse, mutect2, varscan2
- CNTN3 | c.2548G>A p.E850K | Missense Mutation (SNP) | VAF 6/138 reads (4%) | SIFT tolerated (0.17); PolyPhen benign (0.099); catalogued as COSV55170776; called by muse, mutect2
- CTNNA2 | c.406C>T p.R136C | Missense Mutation (SNP) | VAF 25/51 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs756019081, COSV63558850; called by muse, mutect2, varscan2
- DDX5 | c.440_441+2del p.X147_splice | Splice Site (DEL) | VAF 49/190 reads (26%) | catalogued as rs782442161; called by mutect2, pindel, varscan2
- DOCK9 | c.3065A>G p.N1022S (on ENST00000376460 / NM_001366676.2; = p.N1023S on NM_015296.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 10/101 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.821); catalogued as rs750254244; called by muse, mutect2, varscan2
- GABRA6 | c.487T>G p.F163V | Missense Mutation (SNP) | VAF 76/231 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50883052; called by muse, mutect2, varscan2
- MAGEC1 | c.3301T>A p.S1101T | Missense Mutation (SNP) | VAF 6/53 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.044); catalogued as COSV53582009; called by muse, mutect2, varscan2
- MAGEC1 | c.3302C>A p.S1101Y | Missense Mutation (SNP) | VAF 6/53 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.193); catalogued as rs1026591342; called by muse, mutect2, varscan2
- OPN1LW | c.254G>A p.R85H | Missense Mutation (SNP) | VAF 8/9 reads (89%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1557157441; called by muse, mutect2, varscan2
- OR2T8 | c.4G>T p.E2* | Nonsense Mutation (SNP) | VAF 18/70 reads (26%) | catalogued as COSV100178562, COSV60662573; called by muse, mutect2, varscan2
- PNMA8A | c.1075G>T p.A359S | Missense Mutation (SNP) | VAF 38/217 reads (18%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.578); catalogued as COSV58137252; called by muse, mutect2, varscan2
- PSEN2 | c.401G>A p.R134H | Missense Mutation (SNP) | VAF 84/198 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as rs756346917, COSV60915588; called by muse, mutect2, varscan2
- PXDN | c.2024C>T p.A675V | Missense Mutation (SNP) | VAF 59/122 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.909); catalogued as rs748218911, COSV53228594; called by muse, mutect2, varscan2
- SEMA6A | c.2737G>A p.G913R | Missense Mutation (SNP) | VAF 27/113 reads (24%) | SIFT tolerated (0.16); PolyPhen benign (0.178); catalogued as rs765850706, COSV56714683; called by muse, mutect2, varscan2
- SRCIN1 | c.611G>A p.R204H (on ENST00000621492; = p.R170H on NM_025248.3) | Missense Mutation (SNP) | VAF 10/21 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs751827312; called by muse, mutect2, varscan2
- TEKT4 | c.1172G>A p.R391H | Missense Mutation (SNP) | VAF 50/107 reads (47%) | SIFT tolerated (0.12); PolyPhen benign (0.007); catalogued as rs189486507; called by muse, mutect2, varscan2
- VWA3B | c.392G>A p.R131Q | Missense Mutation (SNP) | VAF 19/38 reads (50%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs373644930; called by muse, mutect2, varscan2
- WDR35 | c.579G>A p.M193I | Missense Mutation (SNP) | VAF 39/86 reads (45%) | SIFT tolerated (0.24); PolyPhen benign (0.001); catalogued as rs775429697, COSV55603913; called by muse, mutect2, varscan2
- ZNF341 | c.2219A>C p.D740A (on ENST00000375200 / NM_001282935.1; = p.D733A on NM_032819.4) | Missense Mutation (SNP) | VAF 37/78 reads (47%) | SIFT tolerated (0.1); PolyPhen benign (0.084); catalogued as COSV61007458; called by muse, mutect2, varscan2
- ADGRB3 | c.220T>C p.S74P | Missense Mutation (SNP) | VAF 43/87 reads (49%) | SIFT deleterious (0.04); PolyPhen benign (0.36); called by muse, mutect2, varscan2
- ADNP2 | c.2017T>G p.F673V | Missense Mutation (SNP) | VAF 29/59 reads (49%) | SIFT tolerated (0.6); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- CRACR2A | c.1443G>C p.Q481H | Missense Mutation (SNP) | VAF 42/88 reads (48%) | SIFT tolerated (0.36); PolyPhen benign (0.101); called by muse, mutect2, varscan2
- IGHV2-70D | c.235T>A p.F79I | Missense Mutation (SNP) | VAF 27/71 reads (38%) | SIFT tolerated (0.16); PolyPhen benign (0); called by muse, varscan2
- IGHV2-70D | c.181C>T p.P61S | Missense Mutation (SNP) | VAF 44/90 reads (49%) | SIFT tolerated (0.06); PolyPhen benign (0.125); called by muse, varscan2
- MCMDC2 | c.1655T>C p.V552A | Missense Mutation (SNP) | VAF 77/145 reads (53%) | SIFT tolerated (0.17); PolyPhen benign (0.207); called by muse, mutect2, varscan2
- NLRP8 | c.1026C>A p.C342* | Nonsense Mutation (SNP) | VAF 28/197 reads (14%) | called by muse, mutect2, varscan2
- NLRP9 | c.2416C>G p.L806V | Missense Mutation (SNP) | VAF 42/88 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.823); called by muse, mutect2, varscan2
- PLA2G7 | c.1064C>T p.A355V | Missense Mutation (SNP) | VAF 4/52 reads (8%) | SIFT tolerated (0.21); PolyPhen benign (0.007); called by muse, mutect2
- PLXNB2 | c.4880C>T p.S1627L | Missense Mutation (SNP) | VAF 31/92 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- SCN7A | c.1006T>G p.F336V | Missense Mutation (SNP) | VAF 57/119 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- ADAMTS17 | c.2517C>T p.N839= | Silent (SNP) | VAF 38/157 reads (24%) | catalogued as rs750422781, COSV51488415; called by muse, mutect2, varscan2
- BICDL1 | c.510G>T p.L170= | Silent (SNP) | VAF 23/54 reads (43%) | catalogued as COSV66908839; called by muse, mutect2, varscan2
- BRPF3 | c.2295C>T p.T765= | Silent (SNP) | VAF 36/67 reads (54%) | called by muse, mutect2, varscan2
- DSCAML1 | c.6204C>T p.T2068= (on ENST00000321322; = p.T2008= on NM_020693.4) | Silent (SNP) | VAF 8/108 reads (7%) | catalogued as rs576671392; called by muse, mutect2
- IGHV2-70D | c.201G>A p.E67= | Silent (SNP) | VAF 33/88 reads (38%) | called by muse, varscan2
- IGHV2-70D | c.168C>T p.S56= | Silent (SNP) | VAF 44/81 reads (54%) | catalogued as rs1233195687; called by muse, varscan2
- KCNK15 | c.936G>A p.P312= | Silent (SNP) | VAF 14/41 reads (34%) | called by muse, mutect2, varscan2
- OBSCN | c.2238G>C p.L746= | Silent (SNP) | VAF 21/44 reads (48%) | catalogued as rs1345649158; called by muse, mutect2, varscan2
- ZFR | c.2277A>T p.S759= | Silent (SNP) | VAF 17/78 reads (22%) | called by muse, mutect2, varscan2
- AC016596.1 | chr5:56002438 ins AG | 5'Flank (INS) | VAF 10/19 reads (53%) | called by mutect2, varscan2*
- ARHGAP32 | c.3032-17del | Intron (DEL) | VAF 20/90 reads (22%) | catalogued as rs746852402, COSV59848396; called by mutect2, varscan2
- ATG4C | c.1089+618T>G | Intron (SNP) | VAF 28/67 reads (42%) | called by muse, mutect2, varscan2
- CDHR3 | c.*460A>T | 3'UTR (SNP) | VAF 36/77 reads (47%) | called by muse, mutect2, varscan2
- CMPK1 | c.172-9713T>C | Intron (SNP) | VAF 17/38 reads (45%) | called by muse, mutect2, varscan2
- DAO | c.-9-1335A>C | Intron (SNP) | VAF 17/34 reads (50%) | catalogued as rs1433486794; called by muse, mutect2, varscan2
- DGKE | c.1525-12C>T | Intron (SNP) | VAF 8/20 reads (40%) | called by muse, mutect2, varscan2
- DUSP6 | c.-31G>A | 5'UTR (SNP) | VAF 17/46 reads (37%) | catalogued as rs1396869387; called by muse, mutect2, varscan2
- ENSA | c.*179T>G | 3'UTR (SNP) | VAF 15/35 reads (43%) | called by muse, mutect2, varscan2
- FMN1 | c.*69G>T | 3'UTR (SNP) | VAF 429/594 reads (72%) | catalogued as COSV100568422; called by muse, mutect2
- FYTTD1 | c.*2058G>T | 3'UTR (SNP) | VAF 6/115 reads (5%) | catalogued as COSV99611533; called by muse, mutect2
- GPR68 | c.-129-9217G>A | Intron (SNP) | VAF 8/82 reads (10%) | called by muse, mutect2
- GULP1 | c.91-12G>A | Intron (SNP) | VAF 24/94 reads (26%) | called by muse, mutect2, varscan2
- KLF11 | c.*824G>A | 3'UTR (SNP) | VAF 25/44 reads (57%) | called by muse, mutect2, varscan2
- KPNA4 | c.*5020A>C | 3'UTR (SNP) | VAF 7/42 reads (17%) | catalogued as COSV62076298; called by muse, mutect2, varscan2
- MDM4 | c.*3049C>T | 3'UTR (SNP) | VAF 18/43 reads (42%) | called by muse, mutect2, varscan2
- MICALL2 | c.*116G>A | 3'UTR (SNP) | VAF 17/128 reads (13%) | catalogued as rs778306926, COSV52515655; called by muse, mutect2, varscan2
- MYT1L | c.3075-44A>G | Intron (SNP) | VAF 31/66 reads (47%) | called by muse, mutect2, varscan2
- N6AMT1 | c.*24C>T | 3'UTR (SNP) | VAF 4/37 reads (11%) | called by muse, mutect2, varscan2
- NRXN1 | c.4039-30117T>G | Intron (SNP) | VAF 21/40 reads (53%) | called by muse, mutect2, varscan2
- NTM-AS1 | n.1832T>C | RNA (SNP) | VAF 82/336 reads (24%) | called by muse, mutect2, varscan2
- NUAK1 | c.362-17C>T | Intron (SNP) | VAF 98/213 reads (46%) | called by muse, mutect2, varscan2
- OSGIN1 | n.278G>A | RNA (SNP) | VAF 7/79 reads (9%) | called by muse, mutect2
- PANK2 | chr20:3924527 G>A | 3'Flank (SNP) | VAF 30/68 reads (44%) | called by muse, mutect2, varscan2
- PCMTD1 | c.*2327T>G | 3'UTR (SNP) | VAF 84/173 reads (49%) | catalogued as rs1042198564; called by muse, mutect2, varscan2
- PLA2G2A | c.41-100del | Intron (DEL) | VAF 28/59 reads (47%) | catalogued as rs1302515622; called by mutect2, pindel, varscan2
- PROS1 | c.*1121G>T | 3'UTR (SNP) | VAF 10/124 reads (8%) | called by muse, mutect2
- RNASEH2C | c.172+14C>T | Intron (SNP) | VAF 12/54 reads (22%) | called by muse, mutect2, varscan2
- RND3 | c.-158A>C | 5'UTR (SNP) | VAF 43/79 reads (54%) | called by muse, mutect2, varscan2
- RPAIN | c.-493T>G | 5'UTR (SNP) | VAF 4/40 reads (10%) | called by muse, mutect2
- SENP8 | c.*7A>G | 3'UTR (SNP) | VAF 17/88 reads (19%) | called by muse, mutect2, varscan2
- SH3GL1 | c.-42G>A | 5'UTR (SNP) | VAF 7/23 reads (30%) | called by muse, mutect2, varscan2
- SLC10A1 | c.*832T>G | 3'UTR (SNP) | VAF 15/23 reads (65%) | called by muse, varscan2
- THAP2 | c.*508A>G | 3'UTR (SNP) | VAF 28/72 reads (39%) | catalogued as rs1210289824; called by muse, mutect2, varscan2
- TSPAN13 | c.*904T>C | 3'UTR (SNP) | VAF 10/84 reads (12%) | called by muse, mutect2, varscan2
- UNC5D | c.*3805T>C | 3'UTR (SNP) | VAF 26/46 reads (57%) | catalogued as rs1174851953; called by muse, mutect2, varscan2
- USP15 | c.*190G>C | 3'UTR (SNP) | VAF 8/20 reads (40%) | called by muse, mutect2, varscan2
